TARGET case TARGET-50-PAJLLD — High-Risk Wilms Tumor (TARGET-WT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/acf60505-f228-5882-8728-389e06ab21cc

Demographics
Sex at birth: male; Race: white; Age at index: 3 years; Vital status: Dead; Days to death: 491 days (1.3 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Wilms tumor: ICD-O-3 morphology code: 8960/3; ICD-10 code: C64; Tissue or organ of origin: Kidney, NOS; Classification of tumor: primary; Age at diagnosis: 3.6 years (1,298 days); Year of diagnosis: 1996; Days to last follow up: 491 days (1.3 years); Pediatric kidney staging: Tumor biopsied only at diagnosis, no distant metastasis; Wilms tumor histologic subtype: Unfavorable.
   Treatment given: Protocol identifier: NWTS-5.

Follow-up (1 entry)
- Days to follow up: 491 days (1.3 years); Days to first event: 491 days (1.3 years); First event: Progression; Year of follow up: 1997.

Biospecimens (1 sample)
- Sample TARGET-50-PAJLLD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.

Additional fields from the TARGET clinical supplement workbook TARGET_WT_ClinicalData_Discovery_and_Validation_Percent_Tumor_Nuclei_and_Necrosis_Supplement_20230322.xlsx (sheet WT Data), for sample TARGET-50-PAJLLD-01A:
- Histological Subtype: anaplastic Wilms
- Specimen Type: frozen solid tumor

Additional fields from the TARGET clinical supplement workbook TARGET_WT_ClinicalData_Discovery_and_Validation_Percent_Tumor_Nuclei_and_Necrosis_Supplement_20230322.xlsx (sheet WT Data), for sample TARGET-50-PAJLLD-11A:
- Histological Subtype: anaplastic Wilms
- Specimen Type: Normal solid tissue
- Adequate Tissue (Y/N): N

Additional fields from the TARGET clinical supplement workbook TARGET_WT_ClinicalData_Validation_20230322.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 491
- Stage: IIIB
- ICD-O-3-T: C649
- Histologic Classification of Primary Tumor: DAWT
